Somatic mutation profile of tumor specimen MMRF_1940_1_BM_CD138pos (aliquot MMRF_1940_1_BM_CD138pos_T1_KHS5U_L08714) from MMRF case MMRF_1940, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.6 years (21,779 days).
Specimen MMRF_1940_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ff56742-982a-438b-b122-fb3ac3398862.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1940_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1940_1_PB_Whole_C2_KHS5U_L08713; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c81d0a9-4c2a-439c-a38c-65a826f7fd68

The open-access MAF lists 52 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, 3'UTR 15, Intron 8, Silent 5, 5'UTR 2, Nonsense Mutation 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 16/97 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADRA1A | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as rs777863824, COSV52360695; called by muse, mutect2, varscan2
- CHRNB4 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs780934865; called by muse, mutect2, varscan2
- EBF2 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs201102910, COSV68776774, COSV68779417; called by muse, mutect2, varscan2
- GRM4 | c.1966C>T p.R656* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as rs1258413622; called by muse, mutect2, varscan2
- HECTD4 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs573860704; called by muse, mutect2
- IGHD6-13 | c.7A>G p.S3G | Missense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as rs782751791; called by muse, mutect2, varscan2
- IGLV3-25 | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as rs371240541; called by muse, mutect2, varscan2
- JPH3 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs748061937; called by muse, mutect2, varscan2
- RET | c.3327G>A p.M1109I | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as COSV60686835; called by muse, mutect2
- SLC6A16 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1421264581; called by muse, mutect2, varscan2
- SPPL2A | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753466675; called by muse, mutect2, varscan2
- UNC79 | c.2293C>T p.R765W (on ENST00000393151 / NM_001346218.2; = p.R588W on NM_020818.5) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); catalogued as rs779928359, COSV56378338; called by muse, mutect2, varscan2
- ADAMTS8 | c.2506T>C p.W836R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CASTOR2 | c.264C>A p.F88L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CCDC34 | c.606+8G>A | Splice Region (SNP) | VAF 10/104 reads (10%) | called by muse, varscan2
- CCT8L2 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GDPGP1 | c.716A>G p.D239G | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- INPP5F | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NKX2-8 | c.421C>A p.R141S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- TMEM266 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- LMTK2 | c.1722C>T p.T574= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs768239746; called by muse, mutect2, varscan2
- MEST | c.10C>A p.R4= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV56229321, COSV99784353; called by muse, mutect2
- TTN | c.17094G>A p.V5698= (on ENST00000591111; = p.V4771= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs1013393173, COSV100605840; called by muse, mutect2, varscan2
- UCN3 | c.357G>A p.K119= | Silent (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- VPS28 | c.639C>T p.N213= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs368501757; called by muse, mutect2, varscan2
- ADAM28 | c.*1053T>C | 3'UTR (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- ANKRD36 | c.-108G>A | 5'UTR (SNP) | VAF 6/23 reads (26%) | catalogued as COSV101347200; called by muse, mutect2, varscan2
- ANKRD36 | c.-107C>A | 5'UTR (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2
- ARL14EP | c.-63-1468T>G | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- DCLRE1C | c.973-162del | Intron (DEL) | VAF 4/42 reads (10%) | called by pindel, varscan2
- EPB41L4B | c.*693T>A | 3'UTR (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2
- KCNJ3 | c.*1737T>C | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- LAG3 | c.58+58G>A | Intron (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- LSG1 | c.*982T>C | 3'UTR (SNP) | VAF 16/66 reads (24%) | catalogued as rs1263167652; called by muse, mutect2, varscan2
- MYT1L | c.*1613A>G | 3'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- NRG1 | chr8:32548668 T>C | 5'Flank (SNP) | VAF 22/123 reads (18%) | catalogued as rs1430094313; called by muse, mutect2, varscan2
- OSBPL6 | c.103-3895C>T | Intron (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- PAK3 | c.*321T>C | 3'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- PCDH18 | c.*1417A>C | 3'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- PDP2 | c.*1551C>T | 3'UTR (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- PHGR1 | c.10+94G>A | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as rs369375786; called by muse, mutect2, varscan2
- RFX2 | c.*12G>A | 3'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as rs760352249; called by muse, mutect2, varscan2
- SEPTIN3 | c.1011+883C>A | Intron (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- SLC6A4 | c.*4111A>T | 3'UTR (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- SPRY3 | c.*2795A>C | 3'UTR (SNP) | VAF 20/97 reads (21%) | catalogued as COSV100249235; called by muse, mutect2, varscan2
- ST6GAL2 | c.1319-6254A>G | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as rs1407158854; called by muse, mutect2, varscan2
- STUM | c.*1104G>T | 3'UTR (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- SYT7 | c.*694G>C | 3'UTR (SNP) | VAF 35/102 reads (34%) | called by muse, mutect2, varscan2
- TBCA | c.247-245G>A | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- TOP3A | c.*338A>C | 3'UTR (SNP) | VAF 10/34 reads (29%) | catalogued as rs1005718521; called by muse, mutect2, varscan2
- TRPC6 | c.*319G>A | 3'UTR (SNP) | VAF 15/49 reads (31%) | catalogued as rs371024836; called by muse, mutect2, varscan2
